Somatic mutation profile of tumor specimen TCGA-50-5051-01A (aliquot TCGA-50-5051-01A-21D-1855-08) from TCGA case TCGA-50-5051, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 42.7 years (15,585 days).
Specimen TCGA-50-5051-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c61a0df-1228-4052-b28c-38c44e3d4e60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5051-10A (Blood Derived Normal), aliquot TCGA-50-5051-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99f5aa40-a043-420d-9ec8-9f7f1a420376

The open-access MAF lists 123 somatic variants for this specimen: 88 protein-altering or splice-affecting, 35 silent.
By variant classification: Missense Mutation 77, Silent 35, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 7/14 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50311993, COSV99408348; called by muse, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 13/21 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A2ML1 | c.1601T>A p.L534Q | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV55293413; called by muse, mutect2, varscan2
- ABCC5 | c.1844T>C p.L615P | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV55592718; called by muse, mutect2
- ADAMTS1 | c.2204+2T>C p.X735_splice | Splice Site (SNP) | VAF 44/65 reads (68%) | catalogued as rs113268450, COSV53171386; called by muse, mutect2, varscan2
- ADCY5 | c.2917G>A p.G973R | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs749564195, COSV59200140; called by muse, mutect2, varscan2
- BCORL1 | c.1915C>A p.R639S | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54389806, COSV54399829; called by muse, mutect2, varscan2
- BRINP2 | c.2294C>T p.A765V | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV64178469; called by muse, mutect2
- BTRC | c.1790C>T p.S597F (on ENST00000370187 / NM_033637.4; = p.S561F on NM_003939.5) | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV64579975; called by muse, mutect2, varscan2
- CALB2 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56940339; called by muse, mutect2, varscan2
- CCDC73 | c.731T>A p.I244N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV58800781; called by muse, mutect2, varscan2
- CFAP57 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.677); catalogued as COSV52540557; called by muse, mutect2
- CHAD | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV99366013; called by muse, mutect2, varscan2
- CHRD | c.2609G>T p.R870L | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52609621; called by muse, mutect2, varscan2
- CLIC1 | c.459T>G p.D153E | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV101007416; called by muse, mutect2
- CYP11B2 | c.472C>A p.L158I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.044); catalogued as COSV59996646; called by muse, mutect2
- DDI2 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 5/61 reads (8%) | catalogued as COSV60780219; called by muse, mutect2
- EYA4 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.281); catalogued as COSV62055638; called by muse, mutect2, varscan2
- FAT4 | c.8900G>T p.S2967I | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58673629, COSV58693834; called by muse, mutect2, varscan2
- FGA | c.1641G>T p.R547S | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV57397661, COSV57400384; called by muse, mutect2, varscan2
- FMN2 | c.5137G>T p.G1713* | Nonsense Mutation (SNP) | VAF 27/145 reads (19%) | catalogued as COSV100142103; called by muse, mutect2, varscan2
- FMN2 | c.5138G>T p.G1713V | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60417113, COSV60426470; called by muse, mutect2, varscan2
- GAD2 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99392328; called by muse, mutect2, varscan2
- GAD2 | c.632C>A p.P211Q | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99392334; called by muse, mutect2, varscan2
- GPR31 | c.898C>A p.L300I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as COSV64761302; called by muse, mutect2, varscan2
- GUCY2F | c.2358G>T p.Q786H | Missense Mutation (SNP) | VAF 116/306 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV54304921; called by muse, mutect2, varscan2
- HRNR | c.2696G>T p.G899V | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100913185, COSV64257546; called by muse, mutect2, varscan2
- IFT57 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52710466, COSV99197344; called by muse, mutect2, varscan2
- IGSF8 | c.617T>G p.V206G | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV58758485; called by muse, mutect2
- KLHL14 | c.833T>A p.V278D | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63833787; called by muse, mutect2, varscan2
- KLHL2 | c.1088G>T p.G363V | Missense Mutation (SNP) | VAF 95/462 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56979131; called by muse, varscan2
- KRT7 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1565715180, COSV59331713; called by muse, mutect2, varscan2
- LAPTM5 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.632); catalogued as rs1460990190, COSV53853758; called by muse, mutect2, varscan2
- LRFN2 | c.982C>A p.R328S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs376425369, COSV57829915; called by muse, mutect2, varscan2
- MAGEC1 | c.1145C>G p.S382C | Missense Mutation (SNP) | VAF 80/470 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53576143; called by muse, varscan2
- MAGEC2 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56000178, COSV56001703; called by muse, mutect2
- MED12 | c.2935T>C p.Y979H | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV61345200; called by muse, mutect2
- MYO16 | c.3623C>T p.A1208V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV62753407; called by muse, mutect2
- MYOM2 | c.1681G>T p.A561S | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.204); catalogued as COSV50729602, COSV50766538; called by muse, mutect2, varscan2
- NAE1 | c.1229A>T p.D410V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV51977052; called by muse, mutect2, varscan2
- NDST3 | c.2277C>G p.F759L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV56622489; called by muse, mutect2, varscan2
- NLRC5 | c.5021del p.L1674Rfs*17 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as COSV52654787; called by mutect2, pindel, varscan2
- NLRP4 | c.2389del p.E797Nfs*16 | Frame Shift Del (DEL) | VAF 37/84 reads (44%) | catalogued as COSV56717759; called by mutect2, pindel, varscan2
- NOTCH4 | c.3265C>A p.P1089T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV66681872; called by muse, mutect2, varscan2
- NUP98 | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 100/242 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV61434385; called by muse, varscan2
- OR4M1 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 121/821 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.125); catalogued as rs1187551505, COSV100270867; called by muse, mutect2, varscan2
- OR4M1 | c.119C>A p.P40Q | Missense Mutation (SNP) | VAF 122/814 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as COSV100271311; called by mutect2, varscan2
- PAWR | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147882965; called by muse, mutect2, varscan2
- PDE1C | c.1105T>G p.S369A | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as COSV58518548; called by muse, mutect2, varscan2
- PDPR | c.671G>C p.G224A | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.209); catalogued as COSV55353716; called by muse, mutect2, varscan2
- PLEKHG1 | c.3199C>T p.L1067F | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.048); catalogued as COSV62048653; called by muse, mutect2, varscan2
- POLR1F | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.234); catalogued as COSV55998900; called by muse, mutect2, varscan2
- PRLR | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as COSV51497373; called by muse, mutect2, varscan2
- PTK2 | c.1948A>G p.T650A | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.548); catalogued as rs990488105, COSV61788251; called by muse, mutect2, varscan2
- PTPRM | c.3151C>G p.R1051G | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59867684; called by muse, mutect2, varscan2
- PXDNL | c.2024G>C p.R675P | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV62491753; called by muse, mutect2
- PYCR2 | c.184C>A p.H62N | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV59525114; called by muse, mutect2, varscan2
- RGS7 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV58548028; called by muse, mutect2, varscan2
- RTL5 | c.1685C>A p.A562D | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV65453987; called by muse, mutect2, varscan2
- SEL1L2 | c.1838G>A p.R613K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV53154297; called by muse, mutect2, varscan2
- SLC27A6 | c.445C>A p.R149S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs762529757, COSV52484670, COSV52487450; called by muse, mutect2, varscan2
- SLC36A1 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs201241765, COSV54652094; called by muse, mutect2
- SYCP1 | c.1567C>G p.L523V | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV65698928; called by muse, varscan2
- SYT14 | c.1541A>C p.K514T | Missense Mutation (SNP) | VAF 100/233 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV55057684; called by muse, mutect2, varscan2
- TBPL2 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs761446287, COSV55972986; called by muse, mutect2, varscan2
- TBX19 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV63197864; called by muse, mutect2, varscan2
- TBXT | c.638T>G p.F213C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51618814; called by muse, mutect2, varscan2
- TCHHL1 | c.2045A>G p.D682G | Missense Mutation (SNP) | VAF 127/370 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV64286383; called by muse, mutect2, varscan2
- TECTA | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs770726991, COSV50736339; called by muse, mutect2, varscan2
- TEPSIN | c.1552T>C p.S518P | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56143566; called by muse, mutect2, varscan2
- TFAP2B | c.990G>T p.E330D | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53829014; called by muse, mutect2, varscan2
- TNPO3 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as COSV55283398; called by mutect2, varscan2
- TRPA1 | c.575G>C p.C192S | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV51565942; called by muse, mutect2
- TRPC5 | c.1069G>T p.G357W | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53295355; called by muse, mutect2, varscan2
- TRPS1 | c.3105G>T p.L1035F (on ENST00000220888 / NM_001330599.2; = p.L1048F on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/283 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55249011; called by muse, mutect2, varscan2
- TTC32 | c.326A>T p.D109V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs149286415; called by muse, mutect2, varscan2
- WHRN | c.2698G>T p.V900F | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54332274; called by muse, mutect2, varscan2
- XYLT1 | c.2668C>A p.Q890K | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.114); catalogued as COSV54488649; called by muse, mutect2, varscan2
- ZMYND8 | c.550G>T p.D184Y (on ENST00000311275 / NM_001363741.2; = p.D204Y on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53691341; called by muse, mutect2, varscan2
- ZNF141 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs567110286, COSV53659575; called by muse, mutect2, varscan2
- ZNF800 | c.1710T>A p.N570K | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as COSV56177717; called by muse, mutect2, varscan2
- AC013489.1 | c.815del p.F272Sfs*80 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, varscan2
- DOCK1 | c.3455+3_3455+6del p.X1152_splice | Splice Site (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel
- HEATR5B | c.2628dup p.G877Wfs*15 | Frame Shift Ins (INS) | VAF 39/101 reads (39%) | called by mutect2, pindel, varscan2
- IGHV2-5 | c.154G>T p.G52* | Nonsense Mutation (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- NBPF26 | c.1946G>A p.G649E (on ENST00000620612; = p.G387E on NM_001351372.1) | Missense Mutation (SNP) | VAF 84/156 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- NUP160 | c.3280dup p.Y1094Lfs*10 | Frame Shift Ins (INS) | VAF 39/109 reads (36%) | called by mutect2, pindel, varscan2
- PLCB4 | c.3213_3218del p.X1071_splice | Splice Site (DEL) | VAF 26/158 reads (16%) | called by mutect2, pindel, varscan2
- AGFG2 | c.699C>T p.P233= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV53545334; called by muse, mutect2, varscan2
- AP002748.5 | c.1548C>A p.S516= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV59149907; called by muse, mutect2, varscan2
- APLF | c.1188T>C p.F396= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV58146339; called by muse, mutect2, varscan2
- APP | c.1785A>T p.P595= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV61000631; called by muse, mutect2, varscan2
- AWAT2 | c.918C>A p.L306= | Silent (SNP) | VAF 42/136 reads (31%) | catalogued as COSV99339505; called by muse, mutect2, varscan2
- B3GAT2 | c.252C>T p.A84= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs774281144, COSV57772210; called by muse, mutect2, varscan2
- CACNA1H | c.981C>T p.A327= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs761021717, COSV61985320; called by muse, mutect2
- CCDC150 | c.1671G>T p.L557= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV55875857; called by muse, mutect2, varscan2
- CCNB1 | c.1200C>T p.V400= | Silent (SNP) | VAF 97/275 reads (35%) | catalogued as COSV99841182; called by muse, mutect2, varscan2
- CSMD3 | c.10974T>A p.P3658= (on ENST00000297405 / NM_001363185.1; = p.P3489= on NM_052900.3) | Silent (SNP) | VAF 24/294 reads (8%) | catalogued as COSV52228101; called by muse, mutect2
- EP400 | c.4371G>T p.T1457= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as COSV57776970; called by muse, mutect2, varscan2
- FLT3 | c.2002C>T p.L668= | Silent (SNP) | VAF 47/71 reads (66%) | catalogued as COSV54059323; called by muse, mutect2, varscan2
- GABRA6 | c.1110G>T p.L370= | Silent (SNP) | VAF 84/231 reads (36%) | catalogued as COSV50884869, COSV50898493; called by muse, mutect2, varscan2
- GFRA1 | c.492C>T p.D164= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs79176106, COSV62607798; called by muse, mutect2, varscan2
- GRM7 | c.1743C>A p.I581= | Silent (SNP) | VAF 87/184 reads (47%) | catalogued as rs375970414, COSV63151322; called by muse, mutect2, varscan2
- KALRN | c.819C>T p.D273= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs1166202016, COSV53770828; called by muse, mutect2, varscan2
- LDB2 | c.444C>A p.T148= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV58773509, COSV58785990; called by muse, mutect2, varscan2
- LRP1B | c.3000G>T p.V1000= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV67242424; called by muse, mutect2, varscan2
- LRTM1 | c.837G>T p.P279= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV55554136; called by muse, mutect2, varscan2
- MAMLD1 | c.426C>A p.G142= | Silent (SNP) | VAF 63/191 reads (33%) | catalogued as COSV53377330; called by muse, mutect2, varscan2
- MDN1 | c.6921A>T p.G2307= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV65524276; called by muse, mutect2, varscan2
- MUC16 | c.18663C>A p.L6221= | Silent (SNP) | VAF 50/100 reads (50%) | catalogued as COSV67476621; called by muse, mutect2, varscan2
- NFXL1 | c.1947A>T p.P649= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV61199621; called by muse, mutect2, varscan2
- PCDH19 | c.1605C>T p.A535= | Silent (SNP) | VAF 113/289 reads (39%) | catalogued as rs754032170, COSV55266105; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHB3 | c.615G>A p.Q205= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as rs575727677, COSV50586849; called by muse, mutect2, varscan2
- PCDHGB2 | c.1158G>T p.V386= | Silent (SNP) | VAF 50/141 reads (35%) | catalogued as COSV53977577; called by muse, mutect2, varscan2
- POLL | c.315G>A p.P105= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs369946628, COSV100149971; called by muse, mutect2, varscan2
- RAB5B | c.33G>T p.G11= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV64365030; called by muse, mutect2, varscan2
- ST3GAL4 | c.141C>G p.L47= (on ENST00000392669 / NM_001254758.1; = p.L43= on NM_006278.3) | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as COSV57108365; called by muse, mutect2, varscan2
- ST6GAL2 | c.594C>A p.S198= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV64529557; called by muse, mutect2, varscan2
- TBX20 | c.859C>A p.R287= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1332484439, COSV101282337, COSV104435424; called by muse, mutect2, varscan2
- TENT5D | c.258T>A p.I86= | Silent (SNP) | VAF 56/165 reads (34%) | catalogued as COSV57637536; called by muse, mutect2, varscan2
- TGM5 | c.330G>A p.A110= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV55008756; called by muse, mutect2, varscan2
- ZMYND15 | c.2010C>T p.P670= (on ENST00000433935 / NM_001136046.3; = p.P631= on NM_032265.2) | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV99350868; called by muse, mutect2, varscan2
- ZNF653 | c.726G>T p.V242= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV53403731; called by muse, mutect2, varscan2
